Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A29R, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A29R-06A (Metastatic).

[page 1 of 4]
DOB/Age/Sex:

Location:

Requested by:

Requested on:

Specimen Rcvd:

Accession No.:

Copies to:

HISTOPATHOLOGY REPORT

CLINICAL DETAILS

F49. History of a cutaneous melanoma (L) cheek, shave biopsied 25.5.10 (

This was followed by WE and SNB () - the melanoma was depth 3.5mm, level V, mit 6/mm², final surgical margins 5mm (skin) and 2.5mm (deep). She had a positive (L) cheek sentinel node biopsy, a 5mm dia deposit (), while the two neck SNBs were negative.

* Now clinical local recurrence of left cheek melanoma.

U/S -> 2.5cm hypoechoic hypervascular mass superior to primary surgical scar, and FNA (confirmed recurrent melanoma (

Operation: Wide excision of recurrent melanoma left cheek, in-continuity with a superficial parotidectomy and level 2A nodes.

(L) level I-V neck dissection.

(L) radial forearm free flap reconstruction (Dr l

Specimens: (1) Infra-auricular node (L) neck.

(2) Left mid parotid.

(3) Left neck deep parotid tissue.

(4) Level 1A (L) neck.

(5) Level 1B (L) neck.

(6) Level 2B (L) neck.

(7) Level 3/4 (L) neck.

(8) Level 5 (L) neck.

(9) Cheek, parotid, and Level 2A (L) neck.

Orientation (L) cheek (long suture = superior margin of cheek tumour)

+ superficial parotid (loop suture marks superior margin parotid)

+ neck scar (short suture = posterior margin (L) neck skin).

ICD-0-3

Melanoma, NOS 8720/3

Site: lymph nodes, neck

C49.0

W

6/2/11

FROZEN SECTION REPORT

Fresh tissue was taken from cheek portion of tumour for Tumour Banking.
(Registrar: Dr

MACROSCOPIC DESCRIPTION

(Dr

Nine specimens were received.

Primary Tumour Site Discrepancy		X

1. "INFRA-AURICULAR NODE LEFT NECK". A tan nodule with a small amount of surrounding granular tissue measuring 5mm across. All embedded in one block.

2. "LEFT MID PAROTID". A 4mm tan piece of tissue. All embedded in one block.

3. "LEFT NECK DEEP PAROTID TISSUE". Two pieces of tan tissue. The smaller 4 x 3 x 2mm and the larger 7 x 5 x 4mm. Larger piece bisected and embedded together with smaller piece.

4. "NECK DISSECTION LEVEL 1A". A piece of fatty tissue 62 x 25 x 12mm.
A. Two lymph nodes.

5. "LEFT NECK DISSECTION LEVEL 1B". A submandibular gland measuring 50 x 42 x 30mm with attached fat measuring 36 x 20 x 10mm.

A Unit of

Printed

Page 1 of 4

[page 2 of 4]
Requested by:

MRN/Name

Location:

Accession:

HISTOPATHOLOGY REPORT

- A. Three lymph nodes.
- B. One lymph node bisected.
- C. Representative section of submandibular gland.

6. "LEFT NECK DISSECTION LEVEL IIB". A piece of fibrofatty tissue 52 x 30 x 12mm.

- A-B. Each one lymph node bisected.
- C. Three lymph nodes.
- D. Five lymph nodes.
- E. One lymph node bisected.

7. "LEFT NECK DISSECTION LEVEL IIIA". Irregular fatty tissue measuring 75 x 50 x 10mm.

- A. ?four lymph nodes.
- B. ?five lymph nodes.

8. "LEVEL V LEFT NECK DISSECTION". Irregular fatty tissue 60 x 60 x 20mm.

- A. ?four nodes.
- B. One lymph node bisected.
- C. ?four nodes.

9. "CHEEK, PAROTID AND LEFT NECK DISSECTION LEVEL IIA". The specimen consists of two ellipses of skin joined by intervening fatty tissue. The larger ellipse containing the long suture measures 85 x 50 x 20mm. There is loose fatty tissue from this piece of skin connecting towards parotid tissue which measures 85 x 50 x 20mm. Overlying a portion of the parotid there is a further ellipse of skin marked with a short suture measuring 65 x 30mm. There is additional fatty nodular tissue at the inferior aspect of the specimen measuring 60 x 50 x 15mm the presumed level IIA lymph nodes. There is a loop suture on the portion of the parotid marking the superior edge. The nodule beneath the cheek has been sampled for Tumour Banking. There is a linear scar present over the ellipse of skin at the cheek tumour measuring 30mm in length. The long suture of the cheek margin is designated 12 o'clock with the 12 o'clock portion inked blue and the 6 o'clock portion inked black. In terms of the parotid portion the superficial aspect is inked blue, the deep inked black and the posterior edge inked green. Sectioning of the cheek portion of the specimen begins away from the parotid in sequential sections towards the parotid into sixteen slices. There is a variegated lobular partially-tan tumour involving the first twelve slices measuring 50 x 35 x 20mm. The tumour comes to within 2mm of the resection margin on the inferior side.

The parotid portion of the specimen is also sectioned into sixteen slices. There appear to be three separate tumours, the first in slices 2 and 3 measuring 10 x 9 x 7mm and abutting the deep margin. The second is in slices 6 - 8 again abutting the deep margin and measuring 18 x 15 x 7mm. The third is in slices 10 - 12 measuring 15 x 7 x 6mm.

Blocks:

- A. Three longitudinal sections of proximal margin.
- B. Slice 2.
- C-D. Slice 8.
- E-F. Slice 10. Note: this is the tumour banking site but preserved closest margin is present in block F.
- G-H. Slice 12 bisected.
- J. Slice 16.
- K. Three longitudinal sections of superior margin of parotid.
- L-N. First nodule in slices 2 and 3.
- P-S. Second nodule in slices 7 and 8.
- T-U. Third nodule in slice 10.
- V-W. Slice 13 region of posterior margin of left neck skin.
- X-AA. Level IIA lymph nodes.

[page 3 of 4]
Requested by: :

MRN/Name:

Location:

Accession:

HISTOPATHOLOGY REPORT

X-Y. One lymph node bisected (the lymph node closest to the parotid).
Z. Four lymph nodes.
AA. One lymph node bisected.

Photos:

MICROSCOPIC REPORT

Diagnosis: Large melanoma deposit forming local recurrence in the (L) cheek scar, plus local satellitosis into adjacent subcutis and dermis. Focal deep margin involvement.
Regional nodal metastases to the (L) parotid, forming multiple deposits, plus desmoplastic extranodal component involving the deep surgical margin.
Focal level IIA nodal deposit, with extranodal extension.

Pathological description:

Specimen 9. The (L) cheek excision specimen shows a local scar recurrence, with tumour forming a mass in the subcutis (9B, 9C, 9D, 9E, 9F, 9G, 9H), directly beneath the previous surgical scar (block 9F) and projecting superiorly.

The melanoma has an epithelioid cytomorphology, patchy pigment, mitoses 4/mm².

There is satellitosis in the subcutis (9B), in places it is in the level of cuticular muscle fibres (9C).

Surgical margin: Focal deep margin involvement is seen (block 9E). Satellites are seen within 5mm of the skin edge (blue-inked / 9B).

Other comments: The dermis shows quite severe solar elastosis for this age.

The parotid contains multiple deposits of melanoma (blocks 9L, 9N, 9P, 9Q, 9R, 9S, 9T, 9V, 9W).

It forms rounded masses within the parotid, many of these being nodal deposits. Additionally there is a component of desmoplastic melanoma tracking extranodally, around vessels (eg 9L, 9N).

Lymphatic plugging is seen within the parotid next to a deposit (block 9T).

No perineural invasion seen.

A previous SNB scar site is seen in 9S, 9Q. There is also satellitosis in the dermis (9W) near the scar.

Surgical margin: Extensive parotid bed involvement, with desmoplastic melanoma showing transection over about 8mm (blocks 9L, 9N, 9P, 9Q).

Other comments: The parotid salivary gland itself is normal.

The contiguous level IIA nodes show metastatic melanoma in 1/7 nodes, a 7mm dia deposit with extranodal extension (blocks 9X, 9Y), but clear of surgical margin.

Specimens 1-3. The separate regional nodal specimens show no evidence of malignancy (0/3).

(L) infra-auricular - 0/1 A small node.

(L) mid parotid - 0/1 A small node abutting parotid salivary tissue.

(L) neck deep parotid tissue - 0/1 A small normal node, along with some scant parotid parenchyma.

Specimens 4-8. The (L) selective neck dissection shows no evidence of malignancy (0/32).

Neck dissection level IA - 0/1 A tiny lymph node in fat.

(L) neck dissection level IB - 0/4 A small focus of capsular naevocytes is seen in 5A.
Normal submandibular salivary gland (5C).

(L) neck dissection level IIB - 0/11 Some brown fat is seen in block 6C.

(L) neck dissection level IIIB - 0/8 Some brown fat is seen in block 7B.

(L) neck dissection level V - 0/8 Small nodes.

COMMENT

Consider adjuvant therapy.

[page 4 of 4]
Requested by:

MRN/N
Loca.
Accession

HISTOPATHOLOGY REPORT

SUMMARY

- Skin (L) cheek / WLE - Locally-recurrent MALIGNANT MELANOMA.
Large scar recurrence, with satellitosis in subcutis.
Focal deep margin involvement.
- Superficial parotidectomy - Metastatic MALIGNANT MELANOMA.
Within intraparotid nodes, plus desmoplastic extranodal.
Margin involvement on deep aspect over a 8mm area.
Satellitosis in the dermis.
- Selective (L) neck dissection - Metastatic MALIGNANT MELANOMA (1/42).
A single 7mm dia deposit in level IIA, with extranodal.

REPORTED BY: Dr

)

Source: NCI Genomic Data Commons file 553dda37-188c-477f-86b4-6ddb4e398211 (TCGA-EE-A29R.8DEEF9EA-3585-4047-A2BD-E7AB4DD1306F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).